Somatic mutation profile of tumor specimen MP2PRT-PAVRMB-TMP1-A (aliquot MP2PRT-PAVRMB-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVRMB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,663 days).
Specimen MP2PRT-PAVRMB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3da94de-df34-460b-b2b6-466de81f9849.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRMB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRMB-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0ddbca2-0b0e-4d60-82a9-2a64e13c6741

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SHOC2 | c.4A>G p.S2G | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs267607048, CM095445, COSV54624833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGAP4 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 142/716 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs200375185; called by muse, mutect2, varscan2
- BAAT | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 110/363 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52289057; called by muse, mutect2, varscan2
- CD1D | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs375741058; called by muse, mutect2, varscan2
- CDH20 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 118/445 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1427688843, COSV99405962; called by muse, mutect2, varscan2
- GDPD4 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 117/398 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as rs766316923; called by muse, mutect2, varscan2
- ADAM2 | c.1032T>A p.H344Q | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- IGHV2-26 | chr14:106301383 TGTGTCTCTGTGGTAT>GC | Missense Mutation (DEL) | VAF 84/228 reads (37%) | called by pindel, varscan2*
- LRRN4 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 173/554 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9A | c.4906C>A p.L1636I | Missense Mutation (SNP) | VAF 103/389 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR6C74 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 28/556 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.563); called by muse, mutect2
- SGIP1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 42/513 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2
- GRHL3 | c.387G>A p.K129= (on ENST00000350501 / NM_198174.3; = p.K134= on NM_021180.3) | Silent (SNP) | VAF 113/364 reads (31%) | catalogued as rs908953686; called by muse, mutect2, varscan2
- PCDHA10 | c.1350C>T p.N450= | Silent (SNP) | VAF 276/742 reads (37%) | catalogued as rs782631166, COSV56474466, COSV56496941; called by muse, mutect2, varscan2
- TEX14 | c.1878C>T p.F626= (on ENST00000240361 / NM_001201457.2; = p.F620= on NM_031272.5) | Silent (SNP) | VAF 66/406 reads (16%) | catalogued as rs374631413; called by muse, mutect2, varscan2
- TTC4 | c.756C>T p.F252= | Silent (SNP) | VAF 126/430 reads (29%) | catalogued as rs1460282659; called by muse, mutect2, varscan2
- LEKR1 | c.*625C>A | 3'UTR (SNP) | VAF 100/360 reads (28%) | catalogued as COSV104414628; called by muse, mutect2, varscan2
